Somatic mutation profile of tumor specimen TCGA-W3-AA1O-06A (aliquot TCGA-W3-AA1O-06A-11D-A38G-08) from TCGA case TCGA-W3-AA1O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 85.9 years (31,382 days).
Specimen TCGA-W3-AA1O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 518de910-4991-478b-9507-7afa30d0e06e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-AA1O-10A (Blood Derived Normal), aliquot TCGA-W3-AA1O-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d88f4d78-c4ce-4eb1-9a74-c9510c7b4d33

The open-access MAF lists 899 somatic variants for this specimen: 591 protein-altering or splice-affecting, 288 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 547, Silent 288, Nonsense Mutation 34, Intron 9, RNA 5, Splice Site 4, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 2, 3'UTR 2, 5'UTR 2, 3'Flank 1.

Variants (750 of 899; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2
- BRAF | c.1525G>A p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic; called by muse, mutect2
- HSD3B2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs80358219, CM930411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199472990, CM002310, COSV51255073; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60795621; called by muse, mutect2, varscan2
- TP53 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 45/59 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs763841979, COSV60687178; called by muse, mutect2, varscan2
- ABLIM1 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as rs780339538, COSV53301046; called by muse, mutect2, varscan2
- AC006059.2 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1161903211, COSV100045875; called by muse, mutect2
- AC104452.1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs150998074; called by muse, mutect2, varscan2
- AC126283.2 | c.1123A>C p.I375L | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV101144683; called by muse, mutect2, varscan2
- ACOT4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as rs755709560, COSV58335606; called by muse, mutect2, varscan2
- ACSBG2 | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99397619; called by muse, mutect2, varscan2
- ACTG2 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV100609460; called by muse, mutect2, varscan2
- ACTRT2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101007655; called by muse, mutect2, varscan2
- ADAM11 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV99567776; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAM18 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs61757466, COSV99696035; called by muse, mutect2, varscan2
- ADGRL4 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769722549, COSV66061014, COSV66061808; called by muse, mutect2, varscan2
- AGBL2 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100102046; called by muse, mutect2, varscan2
- AHNAK | c.11770C>T p.R3924* | Nonsense Mutation (SNP) | VAF 128/296 reads (43%) | catalogued as rs866059259, COSV57208909; called by muse, mutect2, varscan2
- AHNAK | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99949305; called by muse, mutect2, varscan2
- AK2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs778787306, COSV100710066; called by muse, varscan2
- AL441992.2 | c.1154T>C p.F385S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100223819; called by muse, mutect2, varscan2
- ALAD | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99474549, COSV99475002; called by muse, mutect2, varscan2
- ALLC | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99378198; called by muse, mutect2, varscan2
- ANKK1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV100393034; called by muse, mutect2, varscan2
- ANKRD30A | c.3460G>A p.E1154K (on ENST00000611781; = p.E1098K on NM_052997.2) | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV64613442, COSV64615097; called by muse, mutect2, varscan2
- ANKRD44 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99985885; called by muse, mutect2, varscan2
- ANKS3 | c.1405A>C p.I469L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100423257; called by muse, mutect2, varscan2
- ANO5 | c.2461C>T p.H821Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.95); catalogued as COSV100202173; called by muse, mutect2, varscan2
- ANPEP | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV55589277; called by muse, mutect2, varscan2
- AP002512.3 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV54406846, COSV54407612; called by muse, mutect2
- APOB | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as rs770369582, COSV51941992; called by muse, mutect2, varscan2
- APOBEC1 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99981233; called by muse, mutect2, varscan2
- APOBEC3H | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100818868; called by muse, mutect2, varscan2
- AR | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs1381810275, COSV101019313, COSV65955582; called by muse, mutect2, varscan2
- ARFGEF3 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.419); catalogued as COSV52466487, COSV99294555; called by muse, mutect2, varscan2
- ARHGAP15 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54493223; called by muse, mutect2, varscan2
- ARHGAP29 | c.2511G>A p.M837I | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99558921; called by muse, mutect2, varscan2
- ARHGAP35 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351091; called by muse, mutect2, varscan2
- ARID1A | c.2075T>A p.I692N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100253156; called by muse, mutect2
- ARL2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs761946079, COSV55860855; called by muse, varscan2
- ATAT1 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100031342; called by muse, mutect2
- ATP10B | c.1988G>A p.R663K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100515652; called by muse, mutect2, varscan2
- ATP10D | c.4187G>A p.G1396E | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV56690226; called by muse, mutect2, varscan2
- ATP7B | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666902; called by muse, mutect2, varscan2
- BANK1 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV100536760; called by muse, mutect2, varscan2
- BAZ1A | c.3412C>T p.R1138C | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867399795, COSV62409242; called by muse, mutect2, varscan2
- BCL11A | c.1484C>T p.S495L (on ENST00000335712 / NM_001365609.1; = p.S529L on NM_018014.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100184748; called by muse, mutect2, varscan2
- BDKRB1 | c.93A>C p.E31D | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99388016; called by muse, mutect2, varscan2
- BICD1 | c.2816G>A p.G939E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV55687278; called by muse, mutect2, varscan2
- BLNK | c.1079T>A p.L360* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99814178; called by muse, mutect2, varscan2
- BNC1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100597442; called by muse, mutect2, varscan2
- BRAF | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99968300; called by muse, mutect2, varscan2
- BTBD7 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 85/167 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs747462916, COSV100598149; called by muse, mutect2, varscan2
- BTC | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.134); catalogued as COSV101201555; called by muse, mutect2
- BUB1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.59); catalogued as COSV100241586; called by muse, mutect2, varscan2
- C11orf87 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100535890; called by muse, mutect2, varscan2
- C1QTNF2 | c.470G>A p.G157E (on ENST00000393975; = p.G112E on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1029022150, COSV67432703; called by muse, mutect2, varscan2
- C4orf50 | c.486G>A p.M162I (on ENST00000324058; = p.M1394I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1488979167, COSV100136135; called by muse, mutect2, varscan2
- C7 | c.831G>A p.W277* | Nonsense Mutation (SNP) | VAF 33/45 reads (73%) | catalogued as COSV57482991; called by muse, mutect2, varscan2
- C7 | c.2317T>C p.C773R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100496492; called by muse, mutect2, varscan2
- C9orf131 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.037); catalogued as COSV100398263; called by muse, mutect2, varscan2
- CA6 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555895182, COSV66262083; called by muse, mutect2, varscan2
- CADM2 | c.812C>T p.P271L (on ENST00000407528 / NM_001167674.2; = p.P273L on NM_153184.4) | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101059104, COSV67372106; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2, varscan2
- CAPN2 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV99689198; called by muse, mutect2, varscan2
- CAPN2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99689204; called by muse, mutect2, varscan2
- CARMIL2 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs760181192, COSV100576231; called by muse, mutect2, varscan2
- CCDC141 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.045); catalogued as rs781383734, COSV99837367; called by muse, mutect2, varscan2
- CCDC158 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101187354; called by muse, mutect2, varscan2
- CCDC33 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV51502624; called by muse, mutect2, varscan2
- CCDC39 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs550719582, COSV99870455; called by muse, mutect2, varscan2
- CCDC39 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1458123630, COSV56483732; called by muse, mutect2
- CCDC73 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs868393270, COSV100067237, COSV58797856; called by muse, mutect2
- CCDC80 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52815168, COSV99245236; called by muse, mutect2, varscan2
- CCDC88C | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV101106109; called by muse, mutect2, varscan2
- CCR9 | c.576A>T p.E192D (on ENST00000357632 / NM_031200.3; = p.E180D on NM_006641.4) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100591766; called by muse, mutect2, varscan2
- CD163L1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.957); catalogued as rs1401899892, COSV100550603, COSV58015062; called by muse, mutect2, varscan2
- CD19 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV100218053, COSV100218247; called by muse, mutect2, varscan2
- CD207 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs868918174, COSV101338589; called by muse, mutect2, varscan2
- CDH10 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV100052903; called by muse, mutect2, varscan2
- CDH8 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs898414408, COSV100183880; called by muse, mutect2, varscan2
- CDS2 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100986171; called by muse, mutect2, varscan2
- CENPE | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99478942; called by muse, mutect2, varscan2
- CENPF | c.3821C>T p.S1274L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs746908378, COSV65272870; called by muse, mutect2, varscan2
- CEP20 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as COSV99739967; called by muse, mutect2, varscan2
- CFAP54 | c.7087G>A p.D2363N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as COSV100733302; called by mutect2, varscan2
- CFHR2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804414, COSV66381812; called by muse, mutect2, varscan2
- CFHR3 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs763593553, COSV100807743; called by muse, mutect2, varscan2
- CFHR4 | c.1292G>A p.G431E (on ENST00000367416 / NM_001201551.2; = p.G185E on NM_006684.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV52229902; called by muse, mutect2, varscan2
- CFHR5 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs774353375, COSV56817855; called by muse, mutect2, varscan2
- CGNL1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99849018; called by muse, mutect2, varscan2
- CHD5 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 84/115 reads (73%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV52425620; called by muse, mutect2, varscan2
- CHRNA4 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100937470; called by muse, mutect2, varscan2
- CHRNA6 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99373390; called by muse, mutect2, varscan2
- CIITA | c.1286G>A p.W429* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100162530; called by muse, mutect2, varscan2
- CILP2 | c.2605G>A p.G869S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs753821958, COSV99365124; called by muse, mutect2, varscan2
- CLASP2 | c.4453G>T p.G1485C (on ENST00000359576; = p.G1484C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100224246; called by muse, mutect2, varscan2
- CLCA4 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99760771; called by muse, mutect2, varscan2
- CLCN4 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101073978; called by muse, mutect2, varscan2
- CLEC4F | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99713926, COSV99713975; called by muse, mutect2, varscan2
- CLK1 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV58432616; called by muse, mutect2, varscan2
- CLSTN2 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV101515905; called by muse, mutect2, varscan2
- CNKSR1 | c.1642C>T p.H548Y (on ENST00000374253 / NM_001297647.2; = p.H541Y on NM_006314.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.361); catalogued as COSV100128458; called by muse, mutect2, varscan2
- CNTLN | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1261751585, COSV99265445; called by muse, mutect2, varscan2
- CNTNAP2 | c.2588G>A p.G863E | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62228419; called by muse, mutect2, varscan2
- COL11A1 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100617913; called by muse, mutect2, varscan2
- COL11A2 | c.4999C>T p.R1667C (on ENST00000341947 / NM_080680.3; = p.R1560C on NM_080679.2) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs759322344, COSV100554459; called by muse, mutect2, varscan2
- COL15A1 | c.3423G>A p.M1141I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV66647764, COSV66648968; called by muse, mutect2, varscan2
- COL20A1 | c.2308C>T p.H770Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100491347; called by muse, mutect2, varscan2
- COL21A1 | c.2354G>A p.G785E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV55166048, COSV55167710; called by muse, mutect2, varscan2
- COL2A1 | c.2329G>A p.G777R | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100477347; called by muse, mutect2, varscan2
- COL4A2 | c.5095C>T p.R1699C | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779097251, COSV100847466; called by muse, mutect2, varscan2
- COL4A4 | c.3493C>A p.P1165T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as COSV100307575; called by muse, mutect2, varscan2
- COL6A3 | c.4112G>A p.R1371K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1281093215, COSV99800888; called by muse, mutect2, varscan2
- COL7A1 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs41290692, COSV100097514; called by muse, mutect2, varscan2
- CPSF3 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV99433263; called by muse, mutect2, varscan2
- CR2 | c.976A>T p.T326S | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100889698; called by muse, mutect2, varscan2
- CREB3L1 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs769383549, COSV99915267; called by muse, mutect2, varscan2
- CREBBP | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99271642; called by muse, mutect2, varscan2
- CRHBP | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188560; called by muse, mutect2, varscan2
- CRYBB2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101236767; called by muse, mutect2, varscan2
- CSF2RB | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148516448, COSV53260494; called by muse, mutect2, varscan2
- CSMD1 | c.7880C>T p.S2627F (on ENST00000520002; = p.S2626F on NM_033225.6) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs267601891, COSV59284813; called by muse, mutect2, varscan2
- CSMD2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as rs774156082, COSV99585362, COSV99594540; called by muse, mutect2, varscan2
- CTCFL | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs752729345, COSV99713235; called by muse, varscan2
- CWF19L2 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV99979766; called by muse, mutect2, varscan2
- CYP2A7 | c.592T>C p.F198L | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as COSV99394467; called by muse, mutect2, varscan2
- DCD | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV53201171; called by muse, mutect2, varscan2
- DCDC1 | c.5095C>T p.R1699C (on ENST00000597505 / NM_001367979.1; = p.R806C on NM_020869.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780083549, COSV100360754; called by muse, mutect2, varscan2
- DCSTAMP | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 59/154 reads (38%) | catalogued as COSV99886912; called by muse, mutect2, varscan2
- DDX1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51839923; called by muse, mutect2, varscan2
- DENND1A | c.598A>C p.I200L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs375263687, COSV101010774; called by muse, mutect2, varscan2
- DGCR2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54220503; called by muse, mutect2, varscan2
- DGKD | c.509C>T p.S170F (on ENST00000264057 / NM_152879.3; = p.S126F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV99897443; called by muse, mutect2, varscan2
- DISP3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs761012254, COSV99609826; called by muse, mutect2, varscan2
- DLG2 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs756630436, COSV54680698; called by muse, mutect2, varscan2
- DNAH10 | c.4477G>A p.E1493K (on ENST00000409039; = p.E1432K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs373563221, COSV68989561; called by muse, mutect2, varscan2
- DNAH2 | c.10966G>A p.E3656K | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV101209559; called by muse, mutect2, varscan2
- DNAH3 | c.4593G>A p.M1531I | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV54551124; called by muse, mutect2, varscan2
- DNAH5 | c.7937C>T p.P2646L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99453426; called by muse, mutect2, varscan2
- DNAH5 | c.5143C>T p.P1715S | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866319812, COSV99453428; called by muse, mutect2, varscan2
- DNAH5 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99453429; called by muse, mutect2, varscan2
- DNAH5 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54232330; called by muse, mutect2, varscan2
- DNAH7 | c.7973C>T p.S2658F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100417160; called by muse, mutect2, varscan2
- DNAH7 | c.6835G>A p.E2279K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV56778275; called by muse, mutect2, varscan2
- DNAH8 | c.11116C>T p.Q3706* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV59431456; called by muse, mutect2, varscan2
- DNAH9 | c.8128G>A p.E2710K | Missense Mutation (SNP) | VAF 69/83 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375772315, COSV52361379; called by muse, mutect2, varscan2
- DNAJC17 | c.384C>T p.I128= | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as rs146094788; called by muse, mutect2, varscan2
- DNAJC2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV99971951; called by muse, mutect2, varscan2
- DNHD1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs772312325, COSV99600881; called by muse, mutect2
- DNPEP | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV99815383; called by muse, mutect2, varscan2
- DOCK2 | c.3342G>A p.M1114I | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99909571, COSV99914909; called by muse, mutect2, varscan2
- DOP1B | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs773107187, COSV101215774; called by muse, mutect2, varscan2
- DSCAML1 | c.3835G>A p.G1279R (on ENST00000321322; = p.G1219R on NM_020693.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762499777, COSV100357000; called by muse, mutect2, varscan2
- DSEL | c.2466G>A p.W822* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100026027; called by muse, mutect2, varscan2
- DTX2 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100184813; called by muse, mutect2, varscan2
- DUOX2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV101199531; called by muse, mutect2, varscan2
- EEFSEC | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99631252; called by muse, mutect2, varscan2
- EML1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1261930229, COSV51743891; called by muse, mutect2, varscan2
- ENAM | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV68537342; called by muse, mutect2, varscan2
- ENAM | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101253301; called by muse, mutect2, varscan2
- EPB41L4B | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101000585; called by muse, mutect2, varscan2
- ERCC6L2 | c.3311C>T p.S1104L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs372436741; called by muse, mutect2
- ERF | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99724816; called by muse, mutect2, varscan2
- ERICH1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs765504989, COSV50637126; called by muse, mutect2, varscan2
- ERICH3 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1422490302, COSV100445474; called by muse, mutect2, varscan2
- ERICH3 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100445475; called by muse, mutect2, varscan2
- ETV1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99624401; called by muse, mutect2, varscan2
- F2RL2 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as rs267600693, COSV56970966, COSV56970981; called by muse, varscan2
- FABP9 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs746460270, COSV66911506; called by muse, mutect2, varscan2
- FAHD2B | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99738253; called by muse, mutect2, varscan2
- FAM102A | c.1034C>T p.T345I (on ENST00000373095 / NM_001035254.3; = p.T203I on NM_203305.2) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as COSV100305623; called by muse, mutect2, varscan2
- FAM107B | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as rs778239622, COSV99473424, COSV99474364; called by muse, mutect2, varscan2
- FAM131A | c.659A>C p.D220A (on ENST00000310585; = p.D251A on NM_144635.5) | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.322); catalogued as COSV99658938; called by muse, mutect2, varscan2
- FAM135B | c.3449G>A p.G1150E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1234932582, COSV52756291; called by muse, mutect2, varscan2
- FAM184A | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100138281; called by muse, mutect2, varscan2
- FAM71B | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100262283; called by muse, mutect2, varscan2
- FANCA | c.3453G>A p.M1151I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99981817; called by muse, mutect2, varscan2
- FANCM | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99951161, COSV99951550; called by muse, mutect2, varscan2
- FASTKD5 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418518; called by muse, mutect2, varscan2
- FBXL2 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99372224; called by muse, mutect2, varscan2
- FCN3 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs554140953, COSV99585498; called by muse, mutect2, varscan2
- FCN3 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99585499; called by muse, mutect2, varscan2
- FCRL6 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.394); catalogued as rs140713881, COSV58941422; called by muse, mutect2, varscan2
- FECH | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023776; called by muse, mutect2, varscan2
- FERMT3 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as COSV99656773; called by muse, mutect2, varscan2
- FEZ1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746056464, COSV99631080; called by muse, mutect2, varscan2
- FGB | c.1245-1G>C p.X415_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as CS064405, COSV100122337, COSV100122549; called by muse, mutect2, varscan2
- FGF14 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as COSV65958675; called by muse, mutect2
- FILIP1 | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.331); catalogued as rs144188799; called by muse, mutect2, varscan2
- FLG | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100911604, COSV100912047; called by muse, mutect2, varscan2
- FLT4 | c.2737C>T p.L913F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99988694; called by muse, varscan2
- FREM1 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100772212; called by muse, mutect2, varscan2
- FRMPD2 | c.2816C>T p.S939L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as rs1163581362, COSV59718204; called by muse, mutect2, varscan2
- FRMPD4 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 73/94 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as rs1224667126, COSV66222803; called by muse, mutect2, varscan2
- FRMPD4 | c.3782C>T p.S1261L | Missense Mutation (SNP) | VAF 63/81 reads (78%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV66213952; called by muse, mutect2, varscan2
- FSD1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs369508403, COSV99696999; called by muse, mutect2, varscan2
- FZD5 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV99776494; called by muse, mutect2, varscan2
- GAP43 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1483101077, COSV59343265, COSV59343333; called by muse, mutect2, varscan2
- GCNT1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100946644; called by muse, mutect2, varscan2
- GIMAP2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs141987826; called by muse, mutect2, varscan2
- GJA10 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101005432; called by muse, mutect2, varscan2
- GLB1L2 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs144822077; called by muse, mutect2, varscan2
- GLIS3 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100174723; called by muse, mutect2, varscan2
- GLRB | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868460883, COSV52413855, COSV52423095; called by muse, mutect2, varscan2
- GOLGA2 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100360287; called by muse, mutect2, varscan2
- GOLGA2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as rs769990416, COSV100360289; called by muse, mutect2, varscan2
- GOLGA2 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV101363235, COSV68597504; called by muse, mutect2, varscan2
- GORAB | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 39/209 reads (19%) | catalogued as COSV100883783; called by muse, mutect2, varscan2
- GP1BA | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 121/151 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs762867101, COSV56700181, COSV99851169; called by muse, mutect2, varscan2
- GPATCH3 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100658898; called by muse, mutect2, varscan2
- GPCPD1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV100980248; called by muse, mutect2, varscan2
- GPR148 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV99998706; called by muse, mutect2, varscan2
- GPR158 | c.3521G>A p.W1174* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100894215; called by muse, mutect2, varscan2
- GRIA1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99601983; called by muse, mutect2, varscan2
- GRIN2B | c.4231G>A p.V1411M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); catalogued as COSV101663173; called by muse, mutect2, varscan2
- GRIP2 | c.3178G>A p.E1060K (on ENST00000619221; = p.E963K on NM_001080423.4) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99817611; called by muse, mutect2, varscan2
- GRM3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64474784; called by muse, mutect2, varscan2
- GZMA | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1182032419, COSV57113813, COSV99956670; called by muse, mutect2, varscan2
- H1-3 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767802986, COSV99768875; called by muse, mutect2, varscan2
- H4C5 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as rs753083420, COSV100748060; called by muse, mutect2, varscan2
- HBB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs33932070, COSV100092912; ClinVar: other; called by muse, mutect2, varscan2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by muse, mutect2, varscan2
- HEATR4 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100620594; called by muse, mutect2, varscan2
- HEPACAM2 | c.1252C>T p.P418S (on ENST00000394468 / NM_001039372.4; = p.P406S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs267601638, COSV59063215; called by muse, mutect2, varscan2
- HEPACAM2 | c.671C>T p.P224L (on ENST00000394468 / NM_001039372.4; = p.P212L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1392629069, COSV100506758; called by muse, mutect2, varscan2
- HERPUD1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs1199045085, COSV100296054; called by muse, mutect2, varscan2
- HFE | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100352673; called by muse, mutect2, varscan2
- HPSE | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.661); catalogued as COSV100264518; called by muse, mutect2, varscan2
- HTRA1 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as COSV100934741; called by muse, mutect2, varscan2
- HTRA1 | c.1024A>T p.I342F | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100934794; called by muse, mutect2, varscan2
- HUWE1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV99473977; called by muse, mutect2, varscan2
- ICAM5 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99703503; called by muse, mutect2, varscan2
- IGFL2 | c.355C>T p.P119S (on ENST00000377693 / NM_001135113.2; = p.P130S on NM_001002915.2) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100890705; called by muse, mutect2
- IGHV1-2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs781817299; called by muse, mutect2, varscan2
- IGSF5 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1269255617, COSV101012129; called by muse, mutect2, varscan2
- IL36RN | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100697297; called by muse, mutect2, varscan2
- IMPG2 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1310427810, COSV99516335; called by muse, mutect2, varscan2
- INPP5F | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs760510999, COSV62821326; called by muse, mutect2, varscan2
- IPO4 | c.1695A>T p.E565D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99938245; called by muse, mutect2, varscan2
- IQCG | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV54566114; called by muse, mutect2, varscan2
- IRF8 | c.1055A>C p.E352A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99236819; called by muse, mutect2
- IRX2 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as rs1183301386, COSV57411784; called by muse, mutect2, varscan2
- ITGA8 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs369955410, COSV65227857; called by muse, mutect2, varscan2
- ITGAD | c.1880G>A p.S627N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV101210565; called by muse, mutect2, varscan2
- ITIH1 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56253279; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- KCNA6 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768920; called by muse, mutect2, varscan2
- KCNA6 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768921; called by muse, mutect2, varscan2
- KCNB1 | c.1109G>A p.W370* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100870581; called by muse, mutect2, varscan2
- KCNB2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV73048910; called by muse, mutect2, varscan2
- KCNB2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.856); catalogued as rs768925064, COSV73050505; called by muse, mutect2, varscan2
- KCNH5 | c.2812A>T p.I938F | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV100527899; called by muse, varscan2
- KCNH5 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs372872099; called by muse, varscan2
- KCNH5 | c.1835T>C p.V612A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100527903; called by muse, mutect2, varscan2
- KCNT2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs1222652636, COSV54077317, COSV54103551; called by muse, mutect2, varscan2
- KIAA0100 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745507140, COSV66495807; called by muse, mutect2
- KIAA0895 | c.1117C>T p.H373Y (on ENST00000297063 / NM_001100425.2; = p.H322Y on NM_015314.3) | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767143; called by muse, mutect2, varscan2
- KIF13B | c.4007C>T p.S1336L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs752941943, COSV101576070; called by muse, varscan2
- KIF13B | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV101580789; called by muse, mutect2, varscan2
- KIRREL2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99384376; called by muse, mutect2, varscan2
- KLHL40 | c.1152+1G>A p.X384_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | catalogued as rs1440284508, COSV99825731; called by muse, mutect2, varscan2
- KMT2B | c.3662G>T p.C1221F | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99720373; called by muse, mutect2, varscan2
- KMT2C | c.9034C>T p.Q3012* | Nonsense Mutation (SNP) | VAF 85/161 reads (53%) | catalogued as COSV51462925; called by muse, mutect2, varscan2
- KRT28 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 127/175 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as rs1258485874, COSV100137698, COSV60684650; called by muse, mutect2, varscan2
- KRT38 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs762648893, COSV55845141; called by muse, mutect2, varscan2
- LAMA2 | c.2579G>A p.G860E | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs778428420, COSV101370783; called by muse, varscan2
- LAMC2 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 105/160 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as COSV99917864; called by muse, mutect2, varscan2
- LAMP5 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as rs146768664; called by muse, mutect2, varscan2
- LARP1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | PolyPhen benign (0); catalogued as rs866464977, COSV100304038; called by muse, mutect2, varscan2
- LARP1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | PolyPhen benign (0); catalogued as COSV100304039; called by muse, mutect2, varscan2
- LAX1 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs746479885, COSV100920091; called by muse, mutect2, varscan2
- LCK | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100288074; called by muse, mutect2, varscan2
- LCNL1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV99812024; called by muse, mutect2, varscan2
- LEPR | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100848448, COSV62745772; called by muse, mutect2, varscan2
- LGR6 | c.488C>T p.S163F (on ENST00000367278 / NM_001017403.1; = p.S111F on NM_021636.3) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV55152606; called by muse, mutect2, varscan2
- LILRA5 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV56641318; called by muse, mutect2, varscan2
- LINS1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV100130499; called by muse, mutect2, varscan2
- LPA | c.4450A>T p.T1484S | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100307924; called by muse, mutect2, varscan2
- LPA | c.3442C>T p.P1148S | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV100307925; called by muse, mutect2, varscan2
- LRCH3 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV100605234, COSV58391398; called by muse, mutect2, varscan2
- LRP1B | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs868652515, COSV67213914; called by muse, mutect2, varscan2
- LRP2 | c.11170G>A p.D3724N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs267598999, COSV55541646, COSV99790001; called by muse, mutect2, varscan2
- LRRC37A3 | c.4720C>T p.P1574S | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100141462; called by muse, mutect2, varscan2
- LUC7L | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs767811000, COSV99551441; called by muse, mutect2, varscan2
- MAB21L2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV58261886; called by muse, mutect2, varscan2
- MACROD2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs866427331, COSV99441873; called by muse, mutect2, varscan2
- MAEL | c.770T>G p.F257C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV100774767; called by muse, mutect2, varscan2
- MAGEB3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs868499328, COSV64396698, COSV64397767; called by muse, mutect2
- MAGEB6 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs868530714, COSV66872666; called by muse, mutect2, varscan2
- MAMDC2 | c.1079G>A p.W360* | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | catalogued as COSV101015778; called by muse, mutect2, varscan2
- MANSC1 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV101115901; called by muse, mutect2
- MARCHF10 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 88/108 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs757486756, COSV100248544; called by muse, mutect2, varscan2
- MARCHF10 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 111/154 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100248545; called by muse, mutect2, varscan2
- MCAM | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV99876929; called by muse, mutect2, varscan2
- MCTP1 | c.2508G>A p.W836* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV56526205; called by muse, mutect2, varscan2
- MECOM | c.1186G>A p.D396N (on ENST00000468789 / NM_001105078.4; = p.D584N on NM_004991.4) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV99245249; called by muse, mutect2, varscan2
- MKI67 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as rs1399052455, COSV100896929; called by muse, mutect2, varscan2
- MLH3 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99470626; called by muse, mutect2
- MME | c.1223G>A p.W408* | Nonsense Mutation (SNP) | VAF 61/116 reads (53%) | catalogued as COSV100852514; called by muse, mutect2, varscan2
- MORC1 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV99227589; called by muse, mutect2, varscan2
- MPP6 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56038113; called by muse, mutect2, varscan2
- MPP7 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746916795, COSV100517832; called by muse, mutect2, varscan2
- MS4A7 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.543); catalogued as COSV55730820; called by muse, mutect2, varscan2
- MSI1 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs769508876, COSV99981695; called by muse, mutect2, varscan2
- MSR1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50512321; called by muse, mutect2, varscan2
- MTERF4 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99612901; called by muse, mutect2, varscan2
- MUC16 | c.40225G>A p.E13409K | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.959); catalogued as COSV101110068; called by muse, mutect2, varscan2
- MUC16 | c.24836C>T p.S8279F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as rs766688650, COSV101201321; called by muse, mutect2, varscan2
- MUC16 | c.16373C>T p.T5458I | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs1426728544, COSV101201326; called by muse, mutect2, varscan2
- MUC16 | c.15580G>A p.E5194K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.192); catalogued as COSV101201327; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2, varscan2
- MUC16 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as rs1222761973, COSV67477107; called by muse, mutect2, varscan2
- MUC17 | c.3005C>T p.T1002I | Missense Mutation (SNP) | VAF 327/636 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs747008417, COSV100074833; called by muse, mutect2, varscan2
- MUC3A | c.8917C>T p.P2973S | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as COSV100115290; called by muse, varscan2
- MYO18B | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs368413159; called by muse, mutect2, varscan2
- MYO18B | c.6478G>A p.E2160K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs371851187; called by muse, mutect2, varscan2
- MYO9A | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614198; called by muse, mutect2, varscan2
- MYO9B | c.5777C>T p.S1926F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99812606; called by muse, mutect2, varscan2
- MYPN | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1345948618, COSV62734265; called by muse, mutect2, varscan2
- MYT1L | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs1489543411, COSV67720855; called by muse, mutect2, varscan2
- NAALAD2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1565527396, COSV100428755; called by muse, mutect2, varscan2
- NALCN | c.2116A>T p.K706* | Nonsense Mutation (SNP) | VAF 31/113 reads (27%) | catalogued as COSV99217291; called by muse, mutect2
- NANP | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as rs766527115, COSV59160208; called by muse, mutect2, varscan2
- NCAPG2 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373939140; called by muse, mutect2, varscan2
- NCK2 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99256831; called by muse, mutect2
- NDST4 | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99997673; called by muse, mutect2, varscan2
- NDUFS1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99261390; called by muse, mutect2, varscan2
- NEK7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV100954753; called by muse, mutect2, varscan2
- NETO1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV55001912, COSV55004052; called by muse, mutect2, varscan2
- NFYB | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99527256; called by muse, mutect2, varscan2
- NLE1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs903522493, COSV99339010; called by muse, mutect2, varscan2
- NME7 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV100891148, COSV63168931; called by muse, mutect2, varscan2
- NOD2 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs104895442, CM015866, COSV100318835; ClinVar: not provided; called by muse, mutect2, varscan2
- NOL10 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 89/174 reads (51%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs755818598, COSV62039841; called by muse, mutect2, varscan2
- NR1H2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99516520; called by muse, mutect2, varscan2
- NRCAM | c.2812C>T p.P938S (on ENST00000379028 / NM_001371124.1; = p.P922S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61034057; called by muse, mutect2, varscan2
- NSA2 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99713761; called by muse, mutect2, varscan2
- NUGGC | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100429725; called by muse, mutect2, varscan2
- NYNRIN | c.4676C>T p.P1559L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV101230681; called by muse, mutect2, varscan2
- OBP2A | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100535679, COSV100535689; called by muse, mutect2, varscan2
- OBSCN | c.14804G>A p.G4935D | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs1350940886, COSV99483498; called by muse, mutect2, varscan2
- OPN3 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087752, COSV59367251; called by muse, mutect2, varscan2
- OR10G8 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as COSV101461874; called by muse, mutect2, varscan2
- OR11L1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.396); catalogued as COSV63315719; called by muse, mutect2, varscan2
- OR12D2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); catalogued as rs111677372, COSV101011443; called by muse, mutect2
- OR13C9 | c.613T>A p.L205M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV99403550; called by muse, mutect2
- OR2B6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55129973; called by muse, varscan2
- OR2T8 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 110/171 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV100178449, COSV60663608; called by muse, mutect2, varscan2
- OR2Y1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV100322844; called by muse, mutect2, varscan2
- OR4A15 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1428184028, COSV59035680; called by muse, mutect2, varscan2
- OR4C6 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs752969636, COSV58603655; called by muse, mutect2, varscan2
- OR4K14 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV100520517; called by muse, mutect2, varscan2
- OR4K17 | c.579T>A p.Y193* | Nonsense Mutation (SNP) | VAF 56/199 reads (28%) | catalogued as COSV100210782; called by muse, mutect2, varscan2
- OR51T1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs201004265; called by muse, mutect2, varscan2
- OR51V1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100343492; called by muse, mutect2, varscan2
- OR52B4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV68768566, COSV68769571; called by muse, mutect2, varscan2
- OR52I1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV100331806; called by muse, mutect2, varscan2
- OR56B1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV57722569; called by muse, mutect2, varscan2
- OR6K6 | c.697G>A p.E233K (on ENST00000368144; = p.E209K on NM_001005184.1) | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.643); catalogued as COSV100933779; called by muse, mutect2, varscan2
- OR7A17 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV59413779; called by muse, mutect2, varscan2
- OR9G1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100380540; called by muse, mutect2, varscan2
- OTULINL | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99947341; called by muse, mutect2, varscan2
- PAK5 | c.1908G>A p.M636I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867092977, COSV62022994, COSV62023860; called by muse, mutect2, varscan2
- PCDH15 | c.4528G>A p.E1510K (on ENST00000644397 / NM_001354429.2; = p.R1470= on NM_001142770.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1218534475, COSV100905483, COSV100905813; called by mutect2, varscan2
- PCDH15 | c.5183G>A p.R1728K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57287519, COSV57294981; called by muse, mutect2, varscan2
- PCDH15 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.456); catalogued as COSV57275583; called by muse, mutect2, varscan2
- PCDH18 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs1430122137, COSV61267510; called by muse, mutect2, varscan2
- PCDHA7 | c.1660T>C p.F554L | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100971751; called by muse, mutect2, varscan2
- PCDHB16 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV53364561; called by muse, mutect2, varscan2
- PCDHB7 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.139); catalogued as rs76427364, COSV104370742, COSV50813898; called by muse, mutect2, varscan2
- PCDHGA2 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV54025486; called by muse, mutect2, varscan2
- PCDHGA7 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV99545716; called by muse, mutect2, varscan2
- PCDHGA9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs964616167, COSV53943996; called by muse, mutect2, varscan2
- PDE1A | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.025); catalogued as COSV100116148, COSV59522097; called by muse, mutect2, varscan2
- PER2 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.957); catalogued as rs1262077676, COSV99612466; called by muse, mutect2, varscan2
- PF4 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99933126; called by muse, mutect2, varscan2
- PFKFB2 | c.1298A>C p.E433A | Missense Mutation (SNP) | VAF 24/39 reads (62%) | PolyPhen possibly damaging (0.824); catalogued as COSV100892045; called by muse, mutect2, varscan2
- PGGHG | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs866530786, COSV101164662; called by muse, mutect2, varscan2
- PHF21A | c.1236T>G p.S412R (on ENST00000418153 / NM_001101802.3; = p.S413R on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV99139235; called by muse, mutect2, varscan2
- PHKA1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868926138, COSV59805391; called by muse, mutect2, varscan2
- PI15 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52641241; called by muse, mutect2, varscan2
- PIK3C2A | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99791147; called by muse, mutect2, varscan2
- PIK3C2G | c.4288G>A p.D1430N (on ENST00000676171; = p.D1389N on NM_004570.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.98); PolyPhen benign (0.022); catalogued as COSV56825580, COSV56829533; called by muse, mutect2
- PIKFYVE | c.5434C>T p.Q1812* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs1244487517, COSV52242080, COSV52245055; called by muse, mutect2, varscan2
- PITPNM1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778673945, COSV100711727; called by muse, mutect2, varscan2
- PIWIL2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100769530; called by muse, mutect2, varscan2
- PKHD1 | c.3028G>A p.G1010R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100584378; called by muse, mutect2, varscan2
- PKHD1L1 | c.6812C>T p.P2271L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV101006743; called by muse, mutect2, varscan2
- PKHD1L1 | c.7544G>A p.R2515K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV101006744; called by muse, mutect2, varscan2
- PKN1 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs780211446, COSV54400517, COSV99660775; called by muse, mutect2, varscan2
- PLA2G4C | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100844030; called by muse, mutect2, varscan2
- PLCB2 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV99542549; called by muse, mutect2, varscan2
- PLCH1 | c.203C>T p.S68F (on ENST00000340059 / NM_001130960.2; = p.S80F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753893161, COSV58200380; called by muse, mutect2, varscan2
- PLCXD3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs182360912, COSV60606280; called by muse, mutect2, varscan2
- PLEKHG1 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs372612259; called by muse, mutect2, varscan2
- PLEKHH2 | c.3626G>A p.R1209K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV99175043; called by muse, mutect2, varscan2
- PLIN4 | c.419T>C p.V140A (on ENST00000301286; = p.V155A on NM_001367868.2) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100014026; called by muse, mutect2
- PLIN5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs749476677, COSV101113659; called by muse, mutect2, varscan2
- PLPPR5 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1364322939, COSV99587819; called by muse, mutect2, varscan2
- PML | c.2284G>A p.G762S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV99167834; called by muse, mutect2, varscan2
- PMS2 | c.1261C>G p.R421G | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as CM164326, COSV56224693, COSV99764517; called by muse, mutect2, varscan2
- PNKD | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1172387897, COSV99298127; called by muse, mutect2, varscan2
- POM121L12 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.267); catalogued as rs746047304, COSV68692144; called by muse, mutect2, varscan2
- PPARGC1A | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV99338528; called by muse, mutect2, varscan2
- PPFIBP2 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as rs371741461; called by muse, mutect2, varscan2
- PPP1R13B | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52455092; called by muse, mutect2
- PPP1R15A | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99079369, COSV99565785; called by muse, varscan2
- PPP2R1B | c.115-1G>T p.X39_splice | Splice Site (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100232368; called by muse, mutect2, varscan2
- PRAMEF1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV100180085; called by muse, mutect2, varscan2
- PRB2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV101231364; called by muse, varscan2
- PREX2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753863699, COSV55794786; called by muse, mutect2, varscan2
- PRLR | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51501072; called by muse, mutect2, varscan2
- PRRC2A | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100784628; called by muse, mutect2, varscan2
- PRUNE2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.293); catalogued as COSV65028078; called by muse, mutect2, varscan2
- PSMB11 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101273620; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.824C>T p.P275L (on ENST00000421990 / NM_001136042.2; = p.P257L on NM_025267.3) | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100799441, COSV104420476; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.823C>T p.P275S (on ENST00000421990 / NM_001136042.2; = p.P257S on NM_025267.3) | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV64184584; called by muse, mutect2, varscan2
- PTGS1 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV99793490; called by muse, mutect2, varscan2
- PTGS2 | c.392T>A p.L131H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.627); catalogued as COSV100821842; called by muse, mutect2, varscan2
- PTPN13 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100365352; called by muse, mutect2, varscan2
- PTPRF | c.2663A>T p.Y888F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100741167; called by muse, mutect2, varscan2
- PTPRN2 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.319); catalogued as COSV101153378; called by muse, mutect2, varscan2
- PTPRT | c.3389A>C p.E1130A | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100630075, COSV61980529; called by muse, mutect2, varscan2
- PYHIN1 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 32/54 reads (59%) | catalogued as rs754349350, COSV63721348; called by muse, mutect2, varscan2
- RANBP10 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444968578, COSV100449467; called by muse, mutect2, varscan2
- RASEF | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100907044; called by muse, mutect2, varscan2
- RASSF6 | c.796C>T p.H266Y (on ENST00000342081 / NM_201431.2; = p.H234Y on NM_177532.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100275147; called by muse, mutect2
- RBM4 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100029725; called by muse, mutect2, varscan2
- RBMS3 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1214338783, COSV56138495, COSV99822759; called by muse, mutect2, varscan2
- RCN2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100312856; called by muse, mutect2, varscan2
- RET | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394441; called by muse, mutect2, varscan2
- RITA1 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100232486; called by muse, mutect2, varscan2
- RNF182 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV70370250; called by muse, mutect2, varscan2
- ROBO2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868459806, COSV59908612; called by muse, mutect2, varscan2
- RP1 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs868697369, COSV55117337, COSV55125832; called by muse, mutect2, varscan2
- RPTN | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as COSV100285713; called by muse, mutect2, varscan2
- RSPO2 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99410269; called by muse, mutect2, varscan2
- RTN1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV50719070; called by muse, mutect2, varscan2
- RTN4RL2 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.091); catalogued as COSV100625482; called by muse, mutect2, varscan2
- SAMD3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs371432532, COSV62384765; called by muse, mutect2, varscan2
- SAMD9L | c.4709G>A p.G1570E | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59079869, COSV59081822; called by muse, mutect2, varscan2
- SATB2 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as COSV53488848, COSV53489861; called by muse, mutect2, varscan2
- SCMH1 | c.373C>T p.P125S (on ENST00000326197 / NM_001031694.2; = p.P78S on NM_012236.4) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100402104, COSV58235272; called by muse, mutect2, varscan2
- SCML1 | c.866G>A p.G289E (on ENST00000380041 / NM_001037540.3; = p.G262E on NM_006746.6) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101193970; called by muse, mutect2, varscan2
- SCN2B | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99635931; called by muse, mutect2, varscan2
- SCN9A | c.4455G>A p.M1485I (on ENST00000303354; = p.M1474I on NM_002977.3) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs866611357, COSV57603278; called by muse, mutect2, varscan2
- SERPINA12 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs750399305, COSV100369801; called by muse, mutect2, varscan2
- SERPINA4 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs989871946, COSV100097441; called by muse, mutect2, varscan2
- SETMAR | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100740897; called by muse, mutect2, varscan2
- SHLD2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100079477; called by muse, mutect2, varscan2
- SLAMF1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV52500314; called by mutect2, varscan2
- SLC11A1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99262409; called by muse, mutect2, varscan2
- SLC12A1 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.546); catalogued as COSV66791553; called by muse, mutect2
- SLC17A4 | c.163A>T p.M55L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100930661; called by muse, mutect2, varscan2
- SLC17A4 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs866352771, COSV64956171; called by muse, mutect2
- SLC1A3 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54320730, COSV99467164, COSV99468143; called by muse, mutect2, varscan2
- SLC28A2 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs375534708; called by muse, mutect2, varscan2
- SLC2A2 | c.945A>T p.Q315H | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100049490; called by muse, mutect2, varscan2
- SLC9A4 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54835976; called by muse, mutect2, varscan2
- SLIT2 | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as rs779153208, COSV56585349; called by muse, mutect2, varscan2
- SLITRK3 | c.2361G>A p.M787I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV53850279, COSV99579967; called by muse, mutect2, varscan2
- SNTG2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.363); catalogued as COSV57985380; called by muse, mutect2, varscan2
- SORCS1 | c.3407C>T p.T1136I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV99549765; called by muse, mutect2, varscan2
- SORL1 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769806986, COSV52762752; called by muse, mutect2, varscan2
- SORL1 | c.2750C>T p.S917F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV99495260; called by muse, mutect2, varscan2
- SORL1 | c.4810G>A p.E1604K | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV52762527; called by muse, mutect2, varscan2
- SPAM1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99773387; called by muse, mutect2, varscan2
- SPAM1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV56146309, COSV99773390; called by muse, mutect2, varscan2
- SPG11 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs775799559, COSV99969428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs563290492, COSV60894431; called by muse, mutect2, varscan2
- SPHKAP | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV60898561; called by muse, mutect2, varscan2
- SPRY4 | c.214C>G p.P72A (on ENST00000434127 / NM_001127496.3; = p.P95A on NM_030964.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100702231; called by muse, mutect2, varscan2
- SPTB | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1228690182, COSV101072386; called by muse, mutect2, varscan2
- SPTBN5 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 43/73 reads (59%) | catalogued as COSV100312096; called by muse, mutect2, varscan2
- SREBF2 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV100761539, COSV100761560; called by muse, mutect2, varscan2
- SRGAP2 | c.2470C>T p.H824Y (on ENST00000624873 / NM_001170637.4; = p.H825Y on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1553377858, COSV99833218; called by muse, mutect2, varscan2
- ST14 | c.1572T>G p.S524R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV99599091; called by muse, mutect2, varscan2
- STK31 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63453951; called by muse, mutect2, varscan2
- STOX2 | c.1654A>G p.K552E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as rs1433188309, COSV100409171; called by muse, mutect2, varscan2
- STXBP5L | c.3538G>A p.D1180N | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as COSV99876182; called by muse, mutect2, varscan2
- STYXL2 | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs753714291, COSV99609802; called by muse, mutect2, varscan2
- SUSD4 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV100663894; called by muse, mutect2
- SYNE1 | c.5311G>A p.D1771N (on ENST00000367255 / NM_182961.4; = p.D1778N on NM_033071.3) | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV99576339; called by muse, mutect2, varscan2
- SYNE2 | c.10654C>T p.P3552S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV100648393; called by muse, mutect2, varscan2
- SYT10 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57337740; called by muse, mutect2, varscan2
- TACR1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs1455015693, COSV59481206; called by muse, mutect2, varscan2
- TACR3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs778964585, COSV59198545; called by muse, mutect2, varscan2
- TAF1L | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as rs775725123, COSV99645321; called by muse, mutect2, varscan2
- TAF8 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs1243138301, COSV100881194; called by muse, mutect2, varscan2
- TANC2 | c.5119G>A p.G1707S | Missense Mutation (SNP) | VAF 96/140 reads (69%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.991); catalogued as COSV101267350, COSV101267655; called by muse, mutect2, varscan2
- TANC2 | c.5120G>A p.G1707D | Missense Mutation (SNP) | VAF 98/144 reads (68%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101267656; called by muse, mutect2, varscan2
- TAOK3 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as COSV101183574; called by muse, mutect2, varscan2
- TAS2R38 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs377342463; called by muse, mutect2, varscan2
- TBC1D17 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs770873433, COSV99680895; called by muse, varscan2
- TBX20 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV101282416, COSV68786504; called by muse, mutect2, varscan2
- TBX5 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as COSV100092005; called by muse, mutect2, varscan2
- TBX6 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1413306539, COSV99661772; called by muse, mutect2, varscan2
- TCAF1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as rs769342310, COSV63518213; called by muse, mutect2, varscan2
- TCTEX1D2 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100308934, COSV57488264; called by muse, mutect2, varscan2
- TESMIN | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1016603750, COSV54831554, COSV99663799; called by muse, mutect2, varscan2
- TEX33 | c.808G>A p.G270R (on ENST00000381821 / NM_001163857.2; = p.G185R on NM_178552.4) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV67821713; called by muse, mutect2, varscan2
- THRAP3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs777332431, COSV63568643; called by muse, mutect2, varscan2
- THSD7B | c.3595G>A p.E1199K (on ENST00000272643; = p.E1197K on NM_001316349.2) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763724242, COSV55705268; called by muse, mutect2
- TIGIT | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as rs1212349351, COSV67329472; called by muse, mutect2, varscan2
- TINF2 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); catalogued as COSV99945694; called by muse, mutect2, varscan2
- TIPIN | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99972492; called by muse, mutect2, varscan2
- TKTL2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs868206304, COSV54918767, COSV99761703; called by muse, mutect2, varscan2
- TMEM132A | c.2479G>A p.E827K (on ENST00000453848 / NM_178031.3; = p.E828K on NM_017870.4) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.801); catalogued as rs747836495, COSV99136996; called by muse, mutect2, varscan2
- TMEM38A | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99495470; called by muse, mutect2, varscan2
- TNFSF15 | c.254-1G>A p.X85_splice | Splice Site (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100928339; called by muse, mutect2, varscan2
- TNIP3 | c.454A>T p.K152* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99284752; called by muse, mutect2, varscan2
- TNKS | c.1631T>G p.L544* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100127766; called by muse, mutect2, varscan2
- TNS3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1562737869, COSV100236261; called by muse, mutect2, varscan2
- TNS3 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100236263; called by muse, mutect2, varscan2
- TNXB | c.8909C>T p.P2970L (on ENST00000647633; = p.P2723L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100926588; called by muse, mutect2, varscan2
- TPBG | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV100869812; called by muse, mutect2, varscan2
- TRIML2 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as COSV100456313; called by muse, mutect2, varscan2
- TRMU | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99324683; called by muse, mutect2, varscan2
- TRPC1 | c.668C>T p.P223L (on ENST00000476941 / NM_001251845.2; = p.P189L on NM_003304.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99859270; called by muse, mutect2, varscan2
- TRPC6 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100723747; called by muse, varscan2
- TRRAP | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV100722855; called by muse, varscan2
- TSBP1 | c.820G>A p.E274K (on ENST00000617061; = p.E277K on NM_006781.5) | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV100898927; called by muse, mutect2, varscan2
- TSKU | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100290225; called by muse, mutect2, varscan2
- TTN | c.81527G>A p.R27176K (on ENST00000591111; = p.R19752K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | PolyPhen probably damaging (0.987); catalogued as rs770715791, COSV100627010; called by muse, mutect2, varscan2
- TTN | c.26125G>A p.D8709N (on ENST00000591111; = p.D7782N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | PolyPhen benign (0.033); catalogued as COSV100627072; called by muse, mutect2, varscan2
- TTN | c.20488G>A p.E6830K (on ENST00000591111; = p.E5903K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | PolyPhen benign (0.178); catalogued as COSV59998877; called by muse, mutect2, varscan2
- TTN | c.19694C>T p.P6565L (on ENST00000591111; = p.P5638L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | PolyPhen probably damaging (0.999); catalogued as rs1299399084, COSV100627078; called by muse, mutect2, varscan2
- TTN | c.16351G>A p.D5451N (on ENST00000591111; = p.D4524N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | PolyPhen benign (0.052); catalogued as rs576904726, COSV59905599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.4804C>T p.P1602S (on ENST00000591111; = p.P1556S on NM_003319.4) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | PolyPhen probably damaging (0.998); catalogued as COSV100627095, COSV60416961; called by muse, mutect2, varscan2
- TTN | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | PolyPhen possibly damaging (0.757); catalogued as rs780003580, COSV100627100; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- UGT8 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV100179341; called by muse, mutect2, varscan2
- UNC13B | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101037196; called by muse, mutect2, varscan2
- UNC13B | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101037199; called by muse, mutect2, varscan2
- UNC79 | c.1973C>T p.P658L (on ENST00000393151 / NM_001346218.2; = p.P481L on NM_020818.5) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99829659; called by muse, mutect2, varscan2
- URB2 | c.3071G>A p.R1024K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99271800; called by muse, mutect2, varscan2
- URGCP | c.1064C>T p.S355F (on ENST00000453200 / NM_001077663.3; = p.S346F on NM_017920.4) | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56252735; called by muse, mutect2, varscan2
- USH1C | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99141607; called by muse, mutect2, varscan2
- USH2A | c.3778C>T p.H1260Y | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV56357936; called by muse, mutect2, varscan2
- USP17L2 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100414713; called by muse, mutect2, varscan2
- USP54 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100161360; called by muse, mutect2, varscan2
- VAT1L | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.757); catalogued as COSV56817246, COSV56819056; called by muse, mutect2, varscan2
- VCAN | c.9329C>T p.S3110F | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.079); catalogued as COSV99427096; called by muse, mutect2, varscan2
- VIPR2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs370731634; called by muse, mutect2, varscan2
- VSIR | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775558013, COSV99823398; called by muse, mutect2, varscan2
- VWA3B | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV101417789; called by muse, mutect2, varscan2
- WASF1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780982950, COSV99661154; called by muse, mutect2, varscan2
- WASL | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 47/93 reads (51%) | catalogued as COSV56132814; called by muse, mutect2, varscan2
- WDTC1 | c.1178C>T p.P393L (on ENST00000319394 / NM_001276252.2; = p.P392L on NM_015023.5) | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV100089472; called by muse, mutect2, varscan2
- XIRP1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs145798293; called by muse, varscan2
- XIRP1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1375163161, COSV100453920; called by muse, varscan2
- ZAN | c.8083G>A p.E2695K | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs373913004, COSV61809278; called by muse, mutect2, varscan2
- ZBBX | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs568097370, COSV56787192, COSV56792897; called by muse, mutect2, varscan2
- ZBED9 | c.3148C>T p.H1050Y | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV71729411; called by muse, mutect2, varscan2
- ZBP1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs764212417, COSV100472931; called by muse, mutect2, varscan2
- ZDBF2 | c.3901C>T p.P1301S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1360577974, COSV100985433; called by muse, mutect2, varscan2
- ZDHHC2 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100025137; called by muse, mutect2, varscan2
- ZFHX4 | c.7784G>A p.G2595E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99266796; called by muse, mutect2, varscan2
- ZFP28 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV100019835; called by muse, mutect2, varscan2
- ZGRF1 | c.4253G>A p.R1418K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV101500662; called by muse, mutect2, varscan2
- ZIM3 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV54144746; called by muse, mutect2, varscan2
- ZNF205 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); catalogued as rs775487028, COSV54622134; called by muse, mutect2, varscan2
- ZNF248 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs201654989, COSV100627716; called by muse, mutect2, varscan2
- ZNF257 | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV71306443; called by muse, mutect2, varscan2
- ZNF267 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100339912; called by muse, mutect2, varscan2
- ZNF320 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs888909086, COSV101206924; called by muse, mutect2, varscan2
- ZNF474 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs776529361, COSV56945728, COSV99682293; called by muse, mutect2, varscan2
- ZNF536 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs1421473169, COSV100835768; called by muse, mutect2
- ZNF543 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100386910; called by muse, mutect2, varscan2
- ZNF680 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.828); catalogued as COSV100549298; called by muse, mutect2, varscan2
- ZNF74 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV100677536; called by muse, mutect2, varscan2
- ZNF821 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100546864; called by muse, mutect2, varscan2
- ZNF831 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs553290407, COSV64040347; called by muse, mutect2, varscan2
- ZNF835 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.306); catalogued as COSV73379166; called by muse, mutect2, varscan2
- ZNF99 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs558219171, COSV68055465, COSV68055886, COSV68056062; called by muse, mutect2, varscan2
- ACACA | c.4168C>T p.P1390S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- C1GALT1C1L | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EHBP1 | c.1435dup p.C479Lfs*8 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- FAT1 | c.12163C>T p.P4055S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAGE2E | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 38/707 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2
- IGHV3-16 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- IGHV3-20 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 100/176 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.848); called by muse, mutect2
- IGHV3OR16-8 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- LCE1F | c.210dup p.G71Wfs*14 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- NRP2 | c.2440+2_2440+3insG | Splice Region (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- RBBP5 | c.608del p.S203* | Frame Shift Del (DEL) | VAF 85/186 reads (46%) | called by mutect2, pindel, varscan2
- ZNF655 | c.1203_1210del p.I401Mfs*6 | Frame Shift Del (DEL) | VAF 38/85 reads (45%) | called by mutect2, pindel, varscan2
- AADACL3 | c.564G>A p.V188= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs745572674, COSV100206861; called by muse, mutect2, varscan2
- ABCA2 | c.6777C>T p.I2259= (on ENST00000614293; = p.I2229= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as rs774210228, COSV99688343; called by muse, mutect2
- ABCA2 | c.1627C>T p.L543= (on ENST00000614293; = p.L513= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99688345; called by muse, mutect2, varscan2
- ABCA2 | c.1626C>T p.H542= (on ENST00000614293; = p.H512= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1255558041, COSV99688346; called by muse, mutect2, varscan2
- ABCA9 | c.4323G>A p.V1441= | Silent (SNP) | VAF 87/122 reads (71%) | catalogued as COSV100383422; called by muse, mutect2, varscan2
- ABCC8 | c.3810C>T p.S1270= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100217657; called by muse, mutect2, varscan2
- ABCD1 | c.1234C>T p.L412= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as COSV99497880; called by muse, mutect2, varscan2
- ACKR2 | c.846G>A p.G282= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as rs767623264, COSV99825712; called by muse, mutect2, varscan2
- ACOXL | c.1206C>T p.L402= (on ENST00000389811 / NM_001371254.1; = p.L372= on NM_001142807.4) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV101095830; called by muse, mutect2
- ACRBP | c.1416C>T p.F472= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1321225946, COSV99976261; called by muse, mutect2, varscan2
- ACVR1 | c.309C>T p.I103= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99718063; called by muse, mutect2, varscan2
- ADAM21 | c.726G>A p.V242= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV99961388; called by muse, mutect2, varscan2
- ADAM29 | c.789G>A p.R263= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV63668058; called by muse, mutect2, varscan2
- ADAMTS20 | c.4821T>C p.S1607= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101240199; called by muse, mutect2, varscan2
- AEBP1 | c.1542G>A p.P514= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs764017513, COSV99789059; called by muse, mutect2, varscan2
- AHCY | c.1155C>T p.F385= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99464445; called by muse, mutect2, varscan2
- ANK3 | c.2517G>A p.T839= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs374626133; called by muse, mutect2, varscan2
- ANKRD26 | c.4152C>T p.F1384= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV101063360; called by muse, mutect2, varscan2
- ANXA10 | c.180G>A p.Q60= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100829110; called by muse, mutect2, varscan2
- AP3M2 | c.417C>T p.I139= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV51528678; called by muse, mutect2, varscan2
- APLNR | c.936C>T p.F312= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs753058631, COSV57241797; called by muse, mutect2, varscan2
- APLP2 | c.1513T>C p.L505= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV99600023; called by muse, mutect2, varscan2
- APLP2 | c.1725C>T p.F575= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99600025; called by muse, mutect2, varscan2
- ATP10D | c.204C>T p.S68= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs771018115, COSV56712370; called by muse, mutect2, varscan2
- ATP5MG | c.300C>A p.G100= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100329280; called by muse, mutect2, varscan2
- ATXN1 | c.1896C>T p.A632= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs777231830, COSV99787546; called by muse, mutect2, varscan2
- BCL11A | c.435C>T p.F145= (on ENST00000335712 / NM_001365609.1; = p.F179= on NM_018014.4) | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV100186375; called by muse, mutect2, varscan2
- BIRC6 | c.1983T>A p.G661= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101428726; called by muse, mutect2, varscan2
- BNIP5 | c.321C>T p.F107= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs1207799617, COSV71325430; called by muse, mutect2, varscan2
- BPIFB3 | c.1071G>A p.L357= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100972408; called by muse, mutect2, varscan2
- BRAF | c.1527A>T p.G509= (on ENST00000288602 / NM_001374244.1; = p.G469= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV99968297; called by muse, mutect2
- BRAF | c.702A>T p.T234= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV99968302; called by muse, mutect2, varscan2
- BRSK2 | c.1641G>A p.K547= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100373089; called by muse, mutect2, varscan2
- C6 | c.1470C>T p.I490= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs760389028, COSV54705258, COSV54712571; called by muse, mutect2, varscan2
- CA10 | c.924G>A p.K308= | Silent (SNP) | VAF 56/75 reads (75%) | catalogued as COSV53340251; called by muse, mutect2, varscan2
- CACNA1C | c.1752C>T p.F584= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs886043677, COSV59694388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.4947C>T p.F1649= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV100701098, COSV100704864; called by muse, mutect2, varscan2
- CACNA1G | c.5889C>T p.F1963= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as COSV100662433; called by muse, mutect2, varscan2
- CACNA1H | c.5169C>T p.A1723= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV62003814; called by muse, mutect2
- CACTIN | c.228G>A p.R76= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs1390195639, COSV99698817; called by muse, mutect2, varscan2
- CAMTA1 | c.4797C>T p.L1599= | Silent (SNP) | VAF 110/195 reads (56%) | catalogued as rs758148116, COSV100352200; called by muse, mutect2, varscan2
- CCDC148 | c.321C>T p.D107= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs778298693, COSV99321337; called by muse, mutect2, varscan2
- CCDC9B | c.1344C>T p.S448= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV101233542; called by muse, mutect2, varscan2
- CD248 | c.597C>T p.A199= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs372761607; called by muse, mutect2, varscan2
- CDH7 | c.813C>T p.V271= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100543111; called by muse, mutect2, varscan2
- CEP104 | c.547C>T p.L183= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs565284471, COSV100986367; called by muse, mutect2, varscan2
- CFAP100 | c.927G>A p.K309= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1278768428, COSV100729396; called by muse, mutect2, varscan2
- CFAP221 | c.1056G>A p.T352= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1286782164, COSV99733055; called by muse, mutect2, varscan2
- CFAP54 | c.7737G>A p.S2579= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1366945117, COSV61570459; called by muse, mutect2, varscan2
- CFAP61 | c.2142G>A p.R714= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV55619190; called by muse, mutect2, varscan2
- CNKSR1 | c.1641C>T p.L547= (on ENST00000374253 / NM_001297647.2; = p.L540= on NM_006314.3) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100128501; called by muse, mutect2, varscan2
- CNTNAP5 | c.489G>A p.G163= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1487609903, COSV70503573; called by muse, mutect2
- CPAMD8 | c.1896C>T p.N632= (on ENST00000651564; = p.N585= on NM_015692.5) | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV99359755; called by muse, mutect2, varscan2
- CSK | c.393C>T p.I131= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV99583861; called by muse, mutect2, varscan2
- CSMD1 | c.1782G>A p.G594= (on ENST00000520002; = p.G593= on NM_033225.6) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1285255643, COSV59379064; called by muse, mutect2, varscan2
- CSPP1 | c.375C>T p.I125= (on ENST00000676605; = p.I84= on NM_024790.6) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV51593401; called by muse, mutect2, varscan2
- CTNND2 | c.1461G>A p.Q487= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100476581, COSV100480520; called by muse, mutect2, varscan2
- CYP4A11 | c.840G>A p.L280= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV60224427; called by muse, mutect2, varscan2
- DCANP1 | c.633C>T p.S211= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs764714089, COSV72345845; called by muse, mutect2, varscan2
- DCLRE1A | c.2592G>A p.E864= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100800471; called by muse, mutect2, varscan2
- DCTN4 | c.1302C>T p.P434= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs1472859669, COSV101437580; called by muse, mutect2, varscan2
- DENND3 | c.2241C>T p.L747= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99371569; called by muse, mutect2, varscan2
- DGKI | c.984G>A p.K328= | Silent (SNP) | VAF 79/157 reads (50%) | catalogued as COSV55969998, COSV99937984; called by muse, mutect2, varscan2
- DIDO1 | c.562C>T p.L188= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs773059417, COSV99826917; called by muse, mutect2, varscan2
- DIP2A | c.1986C>T p.V662= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100596280; called by muse, mutect2, varscan2
- DMBT1 | c.3592C>T p.L1198= (on ENST00000338354 / NM_001377530.1; = p.L699= on NM_004406.3) | Silent (SNP) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- DNAH10 | c.4764C>T p.I1588= (on ENST00000409039; = p.I1527= on NM_207437.3) | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV68999177; called by muse, mutect2, varscan2
- DNER | c.892T>C p.L298= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100519918; called by muse, varscan2
- DNM3 | c.783C>T p.S261= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV100798612; called by muse, mutect2, varscan2
- DOP1B | c.5599C>T p.L1867= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV101215775, COSV99062512; called by muse, mutect2, varscan2
- DOP1B | c.5988C>T p.D1996= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101215776; called by muse, mutect2
- DPEP2 | c.570C>T p.G190= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99263214; called by muse, mutect2, varscan2
- DRD3 | c.942C>T p.P314= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as rs922016075, COSV55679418; called by muse, mutect2, varscan2
- DSCAML1 | c.4797G>A p.T1599= (on ENST00000321322; = p.T1539= on NM_020693.4) | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs202016901; called by muse, mutect2, varscan2
- DSP | c.5637G>A p.R1879= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV101131679; called by muse, mutect2, varscan2
- DST | c.21945C>T p.S7315= (on ENST00000361203 / NM_001374722.1; = p.S4988= on NM_015548.5) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1425366040, COSV99759369; called by muse, mutect2, varscan2
- DZIP1 | c.1350C>T p.I450= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV61271101; called by muse, mutect2, varscan2
- EFCAB12 | c.1449G>A p.E483= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100394790; called by muse, mutect2, varscan2
- EGFLAM | c.540C>T p.F180= | Silent (SNP) | VAF 79/120 reads (66%) | catalogued as COSV59297819; called by muse, mutect2, varscan2
- EGR1 | c.48C>A p.I16= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV53520778, COSV99525580; called by muse, mutect2, varscan2
- EPS15L1 | c.2343G>A p.P781= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs779900053, COSV99933609; called by muse, mutect2, varscan2
- EYA2 | c.117C>T p.T39= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1279826945, COSV100427258; called by muse, mutect2, varscan2
- EYA2 | c.789G>A p.G263= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100427259; called by muse, mutect2, varscan2
- FAAH2 | c.1083C>T p.I361= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as rs868368626, COSV66507895, COSV66509727; called by muse, mutect2, varscan2
- FAHD2B | c.72C>T p.S24= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99738251; called by muse, mutect2, varscan2
- FAM102A | c.1035C>T p.T345= (on ENST00000373095 / NM_001035254.3; = p.T203= on NM_203305.2) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs928593601, COSV55947750; called by muse, mutect2, varscan2
- FAM47A | c.2031G>A p.R677= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as COSV60495404; called by muse, mutect2, varscan2
- FAM47A | c.315C>T p.S105= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV100650041, COSV60493876; called by muse, mutect2, varscan2
- FBN2 | c.1452C>T p.I484= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52539762, COSV99330231; called by muse, mutect2, varscan2
- FFAR2 | c.891C>T p.S297= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99876164; called by muse, mutect2, varscan2
- FILIP1 | c.2469C>T p.F823= | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as COSV52728938; called by muse, mutect2, varscan2
- FMN2 | c.2634C>T p.P878= | Silent (SNP) | VAF 63/97 reads (65%) | catalogued as rs1369118118, COSV100146950; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.693C>T p.I231= | Silent (SNP) | VAF 84/186 reads (45%) | catalogued as COSV58561400; called by muse, mutect2, varscan2
- FRAS1 | c.2193C>T p.D731= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs972344214, COSV99355379; called by muse, mutect2, varscan2
- FRMPD1 | c.1500C>T p.F500= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV66700024; called by muse, mutect2, varscan2
- FRMPD3 | c.3276C>T p.F1092= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV52187365; called by muse, mutect2, varscan2
- FSCN3 | c.621C>T p.S207= | Silent (SNP) | VAF 80/142 reads (56%) | catalogued as COSV99133907; called by muse, mutect2, varscan2
- FYB2 | c.549G>A p.R183= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV58585359; called by muse, mutect2, varscan2
- GGCX | c.1605C>T p.F535= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV52086940; called by muse, mutect2, varscan2
- GGT6 | c.109C>T p.L37= | Silent (SNP) | VAF 33/47 reads (70%) | catalogued as COSV99626827; called by muse, mutect2, varscan2
- GPR158 | c.2553C>T p.S851= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1426753636, COSV66274745; called by muse, mutect2, varscan2
- GPRC5C | c.807C>T p.F269= (on ENST00000652232; = p.F224= on NM_018653.4) | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV61236012; called by muse, mutect2, varscan2
- GREB1 | c.4905G>A p.Q1635= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV52195611, COSV99303655; called by muse, mutect2, varscan2
- GRM2 | c.669C>T p.A223= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99623112; called by muse, mutect2, varscan2
- HAL | c.1006C>T p.L336= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV99701634; called by muse, mutect2, varscan2
- HBB | c.141G>A p.G47= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs1554917961, COSV58942890; ClinVar: likely benign; called by muse, mutect2, varscan2
- HCRTR2 | c.375C>T p.S125= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100904113; called by muse, mutect2, varscan2
- HEATR4 | c.1710C>T p.A570= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as COSV100620596; called by muse, mutect2, varscan2
- HECW1 | c.2871C>T p.F957= | Silent (SNP) | VAF 69/135 reads (51%) | catalogued as COSV67841266; called by muse, mutect2, varscan2
- HHIPL2 | c.162C>T p.P54= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100597053; called by muse, mutect2, varscan2
- HSD11B1L | c.42C>T p.F14= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as rs771610051, COSV56797508; called by muse, mutect2, varscan2
- HTR4 | c.975C>T p.I325= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100089496; called by muse, mutect2, varscan2
- HTT | c.6171C>T p.S2057= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100751171; called by muse, mutect2, varscan2
- IFNL1 | c.225G>A p.G75= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV61318008; called by muse, mutect2, varscan2
- IGHV3-7 | c.138C>T p.F46= | Silent (SNP) | VAF 136/234 reads (58%) | catalogued as rs782332605; called by muse, mutect2, varscan2
- IL1A | c.246G>A p.K82= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV99641492; called by muse, mutect2, varscan2
- IL21R | c.483G>A p.R161= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV61972567; called by muse, mutect2, varscan2
- IMPG2 | c.3222G>A p.G1074= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV99516337; called by muse, mutect2, varscan2
- INHBB | c.1044C>T p.S348= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99736157; called by muse, mutect2, varscan2
- INTS1 | c.3294C>T p.T1098= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as COSV101248273; called by muse, mutect2, varscan2
- ITGA11 | c.1188G>A p.K396= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100242125; called by muse, mutect2, varscan2
- JUP | c.1524G>A p.L508= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as COSV100159783; called by muse, mutect2, varscan2
- KATNIP | c.3570C>T p.L1190= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99851865; called by muse, mutect2, varscan2
- KCNA5 | c.1791G>A p.R597= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99364051, COSV99364152; called by muse, mutect2
- KCNB2 | c.528G>A p.R176= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV73052940; called by muse, mutect2, varscan2
- KCNG4 | c.126G>A p.R42= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV57583011; called by muse, mutect2, varscan2
- KCNK13 | c.375C>T p.I125= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99965899, COSV99965985; called by muse, mutect2, varscan2
- KIF21B | c.2451G>A p.Q817= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as rs758611487, COSV100145047; called by muse, mutect2, varscan2
- KIR2DL3 | c.366C>T p.I122= | Silent (SNP) | VAF 91/418 reads (22%) | catalogued as COSV100668046; called by muse, mutect2, varscan2
- KNCN | c.87C>T p.I29= | Silent (SNP) | VAF 73/134 reads (54%) | catalogued as rs780681973, COSV99606348; called by muse, mutect2, varscan2
- KRT5 | c.1179C>T p.I393= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99358249; called by muse, mutect2, varscan2
- KRT6A | c.498G>A p.Q166= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV58106238; called by muse, mutect2, varscan2
- KRTAP10-8 | c.174C>T p.S58= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100555284; called by muse, mutect2, varscan2
- KRTAP5-3 | c.192G>A p.K64= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV101294522; called by muse, mutect2, varscan2
- LAMA3 | c.9804C>T p.I3268= (on ENST00000313654 / NM_198129.4; = p.I1659= on NM_000227.6) | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs769343146, COSV99335166; called by muse, mutect2, varscan2
- LAMB1 | c.3036C>T p.C1012= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV99741567; called by muse, mutect2, varscan2
- LAMP5 | c.33C>T p.I11= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs780153708, COSV99855681; called by muse, mutect2, varscan2
- LIFR | c.630C>T p.P210= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV99665302, COSV99665471; called by muse, mutect2, varscan2
- LILRA1 | c.252C>T p.P84= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs1256936005, COSV99252106; called by muse, varscan2
- LIPN | c.1068C>T p.L356= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs768454055, COSV101356241; called by muse, mutect2, varscan2
- LOXL2 | c.1773G>A p.T591= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs751726787, COSV101207978; called by muse, mutect2, varscan2
- LRRC6 | c.1197G>A p.S399= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs557554343, COSV99138514; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC7 | c.204C>T p.S68= (on ENST00000651989 / NM_001370785.2; = p.S35= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs1255859425, COSV99229375; called by muse, mutect2, varscan2
- LRTM1 | c.669G>A p.R223= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV55546789; called by muse, mutect2, varscan2
- MACROD2 | c.618G>A p.K206= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99441871; called by muse, mutect2, varscan2
- MAGI1 | c.2301C>T p.L767= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1384375008, COSV100442928; called by muse, mutect2, varscan2
- MAP1S | c.201C>T p.T67= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs1283958497, COSV100141189; called by muse, mutect2, varscan2
- MIA3 | c.817C>T p.L273= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV60514621; called by muse, mutect2, varscan2
- MIGA1 | c.1500C>T p.F500= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100889805; called by muse, mutect2, varscan2
- MKI67 | c.54C>T p.P18= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV64072869; called by muse, mutect2, varscan2
- MMP28 | c.1464C>T p.L488= | Silent (SNP) | VAF 26/35 reads (74%) | catalogued as rs763823902; called by muse, mutect2, varscan2
- MPO | c.1515C>T p.I505= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as COSV99832982; called by muse, mutect2
- MUC16 | c.29019C>T p.S9673= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs760121716, COSV101200183; called by muse, mutect2, varscan2
- MUC16 | c.17379C>T p.I5793= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs763264937, COSV67489580; called by muse, mutect2, varscan2
- MUC16 | c.1716G>A p.L572= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV101201329; called by muse, mutect2, varscan2
- MYH15 | c.4275C>T p.S1425= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV56319940; called by muse, mutect2, varscan2
- MYH15 | c.2020C>T p.L674= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs770912310, COSV99844149; called by muse, mutect2, varscan2
- MYO7A | c.72C>T p.I24= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs397516334, COSV101289255, COSV68686683; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCKAP5 | c.2398C>T p.L800= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV100494125; called by muse, mutect2, varscan2
149 further variants in this file (0 protein-altering or splice-affecting, 129 silent, 20 other) are not listed here.
